MMRF case MMRF_1447 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/abc979e5-dd84-4bfa-9727-b2f396f3a3c5

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 71 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 71.2 years (26,015 days); ISS stage: II; Days to last known disease status: 1,421 days (3.9 years); Days to last follow up: 1,421 days (3.9 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 81 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 125 days; Days to treatment end: 125 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 125 days; Days to treatment end: 125 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 259 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -2 (ECOG 1): M Protein 3.51 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.85 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.81 mg/dL; Immunoglobulin G 48.7 g/L; Immunoglobulin A 0.21 g/L; Immunoglobulin M 0.23 g/L; Beta 2 Microglobulin 4.09 µg/mL; Lactate Dehydrogenase 1.87 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 2.01 ×10⁹/L; Platelets 180 ×10⁹/L; Creatinine 108 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.4 mmol/L; Albumin 36 g/L; Total Protein 9.3 g/dL; Glucose 10.4 mmol/L; C-Reactive Protein 0.096 mg/dL.
- Day 61: M Protein 0.33 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.85 mg/dL; Immunoglobulin G 6.37 g/L; Immunoglobulin A 0.11 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 1.52 µg/mL; Lactate Dehydrogenase 3.07 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 8.8 ×10⁹/L; Absolute Neutrophil 6.51 ×10⁹/L; Platelets 59 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.13 mmol/L; Albumin 36.4 g/L; Total Protein 5.4 g/dL; Glucose 6.88 mmol/L.
- Day 155 (ECOG 2): M Protein 0.24 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.47 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.56 mg/dL; Immunoglobulin G 6.14 g/L; Immunoglobulin A 0.27 g/L; Immunoglobulin M 0.26 g/L; Beta 2 Microglobulin 1.97 µg/mL; Lactate Dehydrogenase 2.8 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 8.9 ×10⁹/L; Absolute Neutrophil 5.6 ×10⁹/L; Platelets 279 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.33 mmol/L; Albumin 40 g/L; Total Protein 7.2 g/dL; Glucose 6.77 mmol/L.
- Day 287 (ECOG 2): M Protein 0.31 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.23 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.06 mg/dL; Immunoglobulin G 8.44 g/L; Immunoglobulin A 0.47 g/L; Immunoglobulin M 0.41 g/L; Beta 2 Microglobulin 3.15 µg/mL; Lactate Dehydrogenase 2.48 µkat/L; Hemoglobin 9.24 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 4.14 ×10⁹/L; Platelets 217 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.58 mmol/L; Albumin 47 g/L; Total Protein 8.4 g/dL; Glucose 10.6 mmol/L.
- Day 355: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.61 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.37 mg/dL; Immunoglobulin G 11.7 g/L; Immunoglobulin A 1.15 g/L; Immunoglobulin M 0.46 g/L; Beta 2 Microglobulin 1.7 µg/mL; Lactate Dehydrogenase 1.87 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.85 ×10⁹/L; Platelets 168 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.38 mmol/L; Albumin 38 g/L; Total Protein 7.6 g/dL; Glucose 7.7 mmol/L.
- Day 460: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.08 mg/dL; Immunoglobulin G 15 g/L; Immunoglobulin A 1.62 g/L; Immunoglobulin M 0.6 g/L; Beta 2 Microglobulin 2.3 µg/mL; Lactate Dehydrogenase 2.23 µkat/L; Hemoglobin 9.18 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 5.78 ×10⁹/L; Platelets 251 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.43 mmol/L; Albumin 42 g/L; Total Protein 8.5 g/dL; Glucose 8.14 mmol/L.
- Day 530: Hemoglobin 8.37 mmol/L; Leukocytes 5.1 ×10⁹/L; Platelets 211 ×10⁹/L.
- Day 642: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.26 mg/dL; Immunoglobulin G 15.7 g/L; Immunoglobulin A 2.37 g/L; Immunoglobulin M 0.59 g/L; Beta 2 Microglobulin 1.92 µg/mL; Lactate Dehydrogenase 1.83 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.79 ×10⁹/L; Platelets 246 ×10⁹/L; Creatinine 89.3 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.3 mmol/L; Albumin 37 g/L; Total Protein 7.7 g/dL; Glucose 7.21 mmol/L.
- Day 699: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.52 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.43 mg/dL; Immunoglobulin G 13.8 g/L; Immunoglobulin A 2.42 g/L; Immunoglobulin M 0.53 g/L; Beta 2 Microglobulin 1.9 µg/mL; Hemoglobin 8.93 mmol/L; Leukocytes 13.9 ×10⁹/L; Absolute Neutrophil 2.59 ×10⁹/L; Platelets 175 ×10⁹/L; Creatinine 96.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.23 mmol/L; Albumin 37 g/L; Total Protein 7 g/dL; Glucose 8.86 mmol/L.
- Day 831: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.87 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.79 mg/dL; Immunoglobulin G 17 g/L; Immunoglobulin A 3.17 g/L; Immunoglobulin M 0.46 g/L; Beta 2 Microglobulin 1.74 µg/mL; Lactate Dehydrogenase 2.23 µkat/L; Hemoglobin 8.87 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 226 ×10⁹/L; Creatinine 118 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.3 mmol/L; Albumin 36 g/L; Total Protein 7.6 g/dL; Glucose 4.07 mmol/L.
- Day 897: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.99 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.14 mg/dL; Immunoglobulin G 14.3 g/L; Immunoglobulin A 2.32 g/L; Immunoglobulin M 0.43 g/L; Hemoglobin 9.49 mmol/L; Leukocytes 5.5 ×10⁹/L; Platelets 187 ×10⁹/L.
- Day 1,007: Hemoglobin 9.67 mmol/L; Leukocytes 4.8 ×10⁹/L; Platelets 198 ×10⁹/L.
- Day 1,070: Hemoglobin 9.42 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 174 ×10⁹/L.
- Day 1,195: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.17 mg/dL; Immunoglobulin G 15.8 g/L; Immunoglobulin A 4.37 g/L; Immunoglobulin M 0.54 g/L; Beta 2 Microglobulin 1.78 µg/mL; Lactate Dehydrogenase 2.38 µkat/L; Hemoglobin 9.49 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 172 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.35 mmol/L; Albumin 37 g/L; Total Protein 8 g/dL; Glucose 6.27 mmol/L.
- Day 1,281: M Protein 0.28 g/dL; Hemoglobin 9.86 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.17 ×10⁹/L; Platelets 152 ×10⁹/L; Creatinine 108 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.18 mmol/L; Albumin 37 g/L; Total Protein 7.7 g/dL; Glucose 7.7 mmol/L.
- Day 1,337: Hemoglobin 9.8 mmol/L; Leukocytes 4.3 ×10⁹/L; Platelets 172 ×10⁹/L.
- Day 1,421: Hemoglobin 10 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 3.01 ×10⁹/L; Platelets 159 ×10⁹/L; Creatinine 118 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.48 mmol/L; Glucose 4.95 mmol/L.

Other clinical attributes
- Day -2: Weight: 76 kg; Height: 175 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_1447_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -2 days.
- Sample MMRF_1447_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -2 days.
